Somatic mutation profile of tumor specimen C3L-06937-01 (aliquot CPT0422700006) from CPTAC case C3L-06937, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G4; Age at diagnosis: 71.1 years (25,953 days).
Specimen C3L-06937-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f395116-dc66-4de1-a47f-3c25fb58eaf6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06937-31 (Blood Derived Normal), aliquot CPT0422690001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bdafc4d7-93b9-4be5-86a3-973cef4338fc

The open-access MAF lists 90 somatic variants for this specimen: 68 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 20, Nonsense Mutation 4, Frame Shift Del 2, Intron 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ESR1 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 30/295 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1131692059, COSV52798756; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RHOA | c.125A>G p.Y42C | Missense Mutation (SNP) | VAF 59/314 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs1057519954, COSV69041523, COSV69041892, COSV69042190; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.3149A>T p.D1050V | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61393426; called by muse, mutect2, varscan2
- ARMC5 | c.2477C>T p.P826L | Missense Mutation (SNP) | VAF 42/505 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.147); catalogued as CM157179; called by muse, mutect2
- C3 | c.1717C>T p.R573W | Missense Mutation (SNP) | VAF 23/309 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs539270017; called by muse, mutect2
- CCDC88C | c.3550G>A p.E1184K | Missense Mutation (SNP) | VAF 40/422 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs771732363; called by muse, mutect2
- CDC37L1 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV67865719; called by muse, mutect2, varscan2
- CDH4 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 40/280 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); catalogued as rs1201669774, COSV64648959; called by muse, mutect2, varscan2
- CHD6 | c.4440G>C p.Q1480H | Missense Mutation (SNP) | VAF 62/417 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs569454917; called by muse, mutect2, varscan2
- CHPF | c.1666C>T p.R556C | Missense Mutation (SNP) | VAF 71/393 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1327634488, COSV60534577; called by muse, mutect2, varscan2
- CIC | c.4261A>C p.S1421R | Missense Mutation (SNP) | VAF 28/425 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV50555227; called by muse, mutect2
- CPO | c.104A>G p.K35R | Missense Mutation (SNP) | VAF 60/262 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV55939850; called by muse, mutect2, varscan2
- CSMD1 | c.7954G>A p.G2652S (on ENST00000520002; = p.G2651S on NM_033225.6) | Missense Mutation (SNP) | VAF 21/340 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1174864202; called by muse, mutect2
- DDX25 | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54989804; called by muse, mutect2, varscan2
- DIO3 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 35/546 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769225945; called by muse, mutect2
- DMD | c.6491C>A p.A2164E | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58898979, COSV58945900; called by muse, mutect2, varscan2
- DOK7 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 43/428 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs763188032, COSV60771988; called by muse, mutect2, varscan2
- GPR37 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 92/504 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV58255245; called by muse, mutect2, varscan2
- IFT140 | c.2816C>T p.S939L | Missense Mutation (SNP) | VAF 35/245 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs575485883, COSV99559775; called by muse, mutect2, varscan2
- KRT5 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 64/394 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as rs374017172; called by muse, mutect2, varscan2
- LOXHD1 | c.6520G>A p.V2174I (on ENST00000642948; = p.V2112I on NM_144612.7) | Missense Mutation (SNP) | VAF 47/343 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.88); catalogued as rs775756430; called by muse, mutect2, varscan2
- MED23 | c.2614C>T p.R872C | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs972306714, COSV63431822; called by muse, mutect2
- MEGF9 | c.1630C>T p.R544W | Missense Mutation (SNP) | VAF 40/425 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751098164, COSV64238054; called by muse, mutect2
- MRPL3 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.557); catalogued as COSV53915805; called by muse, mutect2, varscan2
- MYCT1 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 35/363 reads (10%) | catalogued as COSV65891352; called by muse, mutect2
- NLRP5 | c.1456G>A p.V486M | Missense Mutation (SNP) | VAF 32/424 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as rs367679358, COSV66763171; called by muse, mutect2
- NRXN1 | c.2446C>T p.R816W | Missense Mutation (SNP) | VAF 31/345 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs200325059, COSV58461654; called by muse, mutect2
- PHF3 | c.2017C>T p.R673C | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as rs143313647; called by muse, mutect2
- PKD1L1 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 46/448 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.295); catalogued as rs571084843; called by muse, mutect2
- PREX2 | c.4480C>A p.R1494S | Missense Mutation (SNP) | VAF 65/331 reads (20%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.014); catalogued as rs757884988, COSV55749051; called by muse, mutect2, varscan2
- PRG4 | c.3739C>T p.L1247F | Missense Mutation (SNP) | VAF 59/373 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1283898885; called by muse, mutect2, varscan2
- PTPRS | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 28/221 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as rs758669308; called by muse, mutect2, varscan2
- PXK | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 46/305 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1173988863; called by muse, mutect2
- RAG1 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 16/400 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1159713387, COSV100201226; called by muse, mutect2
- SETDB1 | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 30/316 reads (9%) | catalogued as COSV54980392; called by muse, mutect2
- SHLD1 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 48/551 reads (9%) | SIFT tolerated (0.93); PolyPhen benign (0.03); catalogued as rs566914252; called by muse, mutect2
- SOX9 | c.683C>A p.S228* | Nonsense Mutation (SNP) | VAF 36/275 reads (13%) | catalogued as COSV55423902, COSV55424856; called by muse, mutect2, varscan2
- TENM4 | c.679G>A p.G227S | Missense Mutation (SNP) | VAF 71/397 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as rs1189874053, COSV53630955, COSV99573576; called by muse, mutect2, varscan2
- TMEM132B | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1302745885, COSV54749183; called by muse, mutect2, varscan2
- TMEM200C | c.1544C>T p.S515L | Missense Mutation (SNP) | VAF 34/480 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs765729505; called by muse, mutect2
- TP53 | c.80del p.P27Lfs*17 | Frame Shift Del (DEL) | VAF 35/207 reads (17%) | catalogued as rs1192416464, COSV53662521; called by mutect2, pindel, varscan2
- TP53BP2 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 19/396 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.163); catalogued as rs1279398471, COSV59067757; called by muse, mutect2
- TSSK6 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 60/344 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as COSV99388948; called by muse, mutect2, varscan2
- WASHC2C | c.1808C>G p.A603G | Missense Mutation (SNP) | VAF 19/387 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV60491482; called by muse, mutect2
- WDR70 | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV54270314; called by muse, mutect2
- XIRP2 | c.3964C>T p.R1322* (on ENST00000628543; = p.R1497* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 24/326 reads (7%) | catalogued as rs202158141; called by muse, mutect2
- ZFP28 | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as rs1354291989, COSV100019693; called by muse, mutect2, varscan2
- ZNF648 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 45/460 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.078); catalogued as COSV60571495; called by muse, mutect2
- ADNP | c.2939A>T p.Q980L | Missense Mutation (SNP) | VAF 54/315 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ATP11B | c.511C>T p.H171Y | Missense Mutation (SNP) | VAF 44/490 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- CCDC40 | c.2644A>G p.M882V | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.084); called by mutect2, varscan2
- CFAP97D1 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); called by muse, varscan2
- CTNND1 | c.1614dup p.S539Lfs*5 | Frame Shift Ins (INS) | VAF 34/213 reads (16%) | called by mutect2, pindel, varscan2
- DISP3 | c.1037C>T p.T346I | Missense Mutation (SNP) | VAF 84/327 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- DSEL | c.2134C>G p.L712V | Missense Mutation (SNP) | VAF 70/336 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- ELF3 | c.1028A>G p.E343G | Missense Mutation (SNP) | VAF 39/248 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GRM7 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.105); called by muse, mutect2
- MICU3 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 61/362 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR52L1 | c.387G>T p.E129D | Missense Mutation (SNP) | VAF 36/408 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDH10 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 38/514 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.65); called by muse, mutect2
- PRPF19 | c.685C>T p.L229F | Missense Mutation (SNP) | VAF 39/292 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- RIF1 | c.5827del p.I1943* | Frame Shift Del (DEL) | VAF 28/226 reads (12%) | called by mutect2, pindel, varscan2
- SLC18A3 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 40/508 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- TMEM200C | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 32/554 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- TRRAP | c.6957T>G p.G2319= (on ENST00000359863 / NM_001244580.1; = p.G2301= on NM_003496.3) | Splice Region (SNP) | VAF 41/233 reads (18%) | called by muse, mutect2, varscan2
- TUNAR | c.99A>C p.K33N | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.617); called by muse, mutect2
- WDR72 | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF512B | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.8); called by muse, mutect2
- ADAM19 | c.2490G>A p.S830= | Silent (SNP) | VAF 63/337 reads (19%) | catalogued as rs764968777, COSV57427459; called by muse, mutect2, varscan2
- ADGRL2 | c.1203T>A p.P401= | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as COSV54692520; called by muse, varscan2
- ANKRD29 | c.642A>G p.A214= | Silent (SNP) | VAF 24/172 reads (14%) | catalogued as rs902779487; called by muse, mutect2, varscan2
- CCDC177 | c.606G>A p.P202= | Silent (SNP) | VAF 28/250 reads (11%) | called by muse, mutect2, varscan2
- CEP192 | c.5379T>C p.S1793= | Silent (SNP) | VAF 19/285 reads (7%) | called by muse, mutect2
- COL6A3 | c.3789C>T p.D1263= | Silent (SNP) | VAF 52/370 reads (14%) | catalogued as rs779279055, COSV55095278; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYLD | c.1593G>A p.A531= | Silent (SNP) | VAF 38/442 reads (9%) | called by muse, mutect2
- CYP1B1 | c.759G>A p.P253= | Silent (SNP) | VAF 35/472 reads (7%) | called by muse, mutect2
- DNHD1 | c.1497G>A p.Q499= | Silent (SNP) | VAF 38/439 reads (9%) | called by muse, mutect2
- KMT2D | c.1449G>A p.L483= | Silent (SNP) | VAF 46/535 reads (9%) | called by muse, mutect2
- MMP11 | c.978C>T p.P326= | Silent (SNP) | VAF 99/450 reads (22%) | catalogued as rs751397617; called by muse, mutect2, varscan2
- PCDHB11 | c.2028G>A p.A676= | Silent (SNP) | VAF 87/526 reads (17%) | catalogued as rs543077450, COSV61312181; called by muse, mutect2, varscan2
- PCSK2 | c.930C>T p.D310= | Silent (SNP) | VAF 22/412 reads (5%) | catalogued as rs372965651; called by muse, mutect2
- PSD3 | c.1449A>G p.Q483= | Silent (SNP) | VAF 80/415 reads (19%) | called by muse, mutect2, varscan2
- RFPL1 | c.171C>T p.C57= | Silent (SNP) | VAF 109/496 reads (22%) | catalogued as rs771644258; called by muse, mutect2, varscan2
- TAS1R3 | c.1818G>A p.L606= | Silent (SNP) | VAF 48/447 reads (11%) | catalogued as rs1322026934; called by muse, mutect2, varscan2
- TMPRSS6 | c.882G>A p.A294= | Silent (SNP) | VAF 35/474 reads (7%) | catalogued as rs370192027; ClinVar: uncertain significance; called by muse, mutect2
- TRANK1 | c.4390C>T p.L1464= | Silent (SNP) | VAF 45/227 reads (20%) | called by muse, mutect2, varscan2
- TSPAN4 | c.711C>T p.C237= | Silent (SNP) | VAF 27/256 reads (11%) | catalogued as rs767708744; called by muse, mutect2, varscan2
- ZNF836 | c.267G>A p.R89= | Silent (SNP) | VAF 45/230 reads (20%) | called by muse, mutect2, varscan2
- LIMCH1 | c.936-5909C>T | Intron (SNP) | VAF 27/359 reads (8%) | catalogued as rs1252547979; called by muse, mutect2
- MARCHF8 | c.242+562C>T | Intron (SNP) | VAF 43/283 reads (15%) | called by muse, mutect2, varscan2
